Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046469-09A (aliquot TARGET-15-SJMPAL046469-09A-01D) from TARGET case TARGET-15-SJMPAL046469, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,551 days).
Specimen TARGET-15-SJMPAL046469-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddfb563a-c215-4981-b57a-c5a9fdf3efc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046469-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046469-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a664b3ca-421d-4374-981c-4d42aea4c389

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 3, Nonsense Mutation 3, 5'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs913400724; called by muse, mutect2, varscan2
- CHD9 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV68298164; called by mutect2, varscan2
- FN1 | c.3424G>A p.G1142S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1359530623, COSV100116263, COSV60550169; called by muse, mutect2, varscan2
- NOS1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as rs1245413261, COSV57613602, COSV57617823; called by muse, mutect2, varscan2
- OTOGL | c.5437C>A p.Q1813K (on ENST00000547103; = p.Q1804K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV54015814; called by muse, varscan2
- PRG4 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV66623524; called by muse, mutect2, varscan2
- ANKFY1 | c.2386G>T p.V796L (on ENST00000341657 / NM_001330063.2; = p.V797L on NM_016376.5) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, varscan2
- ARID1B | c.1958A>T p.D653V | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CBFB | c.268dup p.R90Kfs*26 | Frame Shift Ins (INS) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- DPH7 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NPFFR1 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OBSCN | c.11030C>A p.A3677D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); called by muse, varscan2
- PDCD4 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SFTPA1 | c.686C>A p.T229K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SHISA6 | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- SLC35F3 | c.595C>A p.L199I (on ENST00000366617 / NM_001300845.1; = p.L268I on NM_173508.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A9 | c.1053G>T p.Q351H (on ENST00000360584 / NM_201649.4; = p.Q297H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- SNX6 | c.429-1G>T p.X143_splice (on ENST00000652385; = p.X15_splice on NM_021249.5) | Splice Site (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- SVEP1 | c.2770G>T p.V924L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.437); called by muse, mutect2
- TADA2B | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- UBASH3B | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- WIZ | c.3499G>T p.A1167S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- FOXI3 | c.843G>T p.L281= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101230946; called by mutect2, varscan2
- KCTD19 | c.315G>T p.L105= | Silent (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- LEO1 | c.1134G>T p.L378= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- PRELP | c.225C>A p.R75= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs200948130, COSV58116424; called by mutect2, varscan2
- PTH2R | c.666C>A p.S222= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55919832; called by muse, mutect2
- CIAO3 | c.163-283T>C | Intron (SNP) | VAF 15/50 reads (30%) | catalogued as rs377019932; called by muse, mutect2, varscan2
- DNAJC13 | c.3183-213C>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, varscan2
- DST | c.4297-2820G>T | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99756115; called by muse, mutect2, varscan2
- NPIPA8 | chr16:18337479 C>G | 5'Flank (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128850 C>A | 5'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
